Somatic mutation profile of tumor specimen TCGA-DD-AACU-01A (aliquot TCGA-DD-AACU-01A-11D-A40R-10) from TCGA case TCGA-DD-AACU, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.2 years (21,606 days).
Specimen TCGA-DD-AACU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5af26c9a-b728-465b-9f46-426264ab8679.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACU-10A (Blood Derived Normal), aliquot TCGA-DD-AACU-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e75494ce-85d7-4a71-8ca4-780e31950533

The open-access MAF lists 123 somatic variants for this specimen: 100 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 20, Splice Site 6, Nonsense Mutation 5, Intron 3, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 38/65 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs483352695, CM942294, COSV52664850, COSV52707693, COSV52949209, COSV53107767; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAD9 | c.885G>C p.V295= | Splice Region (SNP) | VAF 34/115 reads (30%) | catalogued as COSV100459438; called by muse, mutect2, varscan2
- ACSM2A | c.1645A>C p.N549H (on ENST00000219054; = p.N470H on NM_001308169.2) | Missense Mutation (SNP) | VAF 67/104 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV99525752; called by muse, mutect2, varscan2
- ACSM4 | c.1575G>T p.K525N | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as COSV101257410; called by muse, mutect2, varscan2
- ANK3 | c.6692A>T p.N2231I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as COSV55061211, COSV99782508; called by muse, mutect2, varscan2
- ASH2L | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.201); catalogued as COSV99167050; called by muse, mutect2, varscan2
- ATP10A | c.2023G>C p.D675H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as COSV100791559, COSV63522916; called by muse, mutect2, varscan2
- C1RL | c.37A>T p.R13* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99864957; called by muse, mutect2, varscan2
- CACNA1E | c.3314G>T p.R1105I | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV62384516; called by muse, mutect2, varscan2
- CAND2 | c.1424T>C p.M475T (on ENST00000456430 / NM_001162499.2; = p.M382T on NM_012298.3) | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV99929851; called by muse, mutect2
- CATSPER1 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs748502205, COSV100376270; called by muse, mutect2, varscan2
- CHRD | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV99200825; called by muse, mutect2, varscan2
- CHST15 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as rs765085481, COSV100655293; called by muse, mutect2, varscan2
- COL19A1 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100507582; called by muse, mutect2, varscan2
- CSMD3 | c.1896C>A p.S632R (on ENST00000297405 / NM_001363185.1; = p.S528R on NM_052900.3) | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99848703; called by muse, mutect2, varscan2
- CTDSPL2 | c.557A>T p.E186V | Missense Mutation (SNP) | VAF 150/407 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV99526764, COSV99527258; called by muse, mutect2, varscan2
- CTNNA2 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.9); catalogued as COSV100562111; called by muse, mutect2, varscan2
- CYP11A1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs763099365, COSV51430559; called by muse, mutect2, varscan2
- CYP17A1 | c.13G>C p.V5L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100882146; called by muse, mutect2, varscan2
- DACT1 | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100242143; called by muse, mutect2, varscan2
- DBT | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100923635; called by muse, mutect2, varscan2
- DCDC1 | c.3343C>T p.P1115S (on ENST00000597505 / NM_001367979.1; = p.P222S on NM_020869.3) | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV100338825; called by muse, mutect2
- DIPK2B | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 47/57 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100933497; called by muse, mutect2, varscan2
- DNAH7 | c.11293G>A p.D3765N | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.787); catalogued as rs769961852, COSV56773102; called by muse, mutect2, varscan2
- DNAH7 | c.354T>A p.H118Q | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100417723; called by muse, mutect2, varscan2
- DYNC2H1 | c.8999T>C p.L3000P | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519857; called by muse, mutect2
- ECEL1 | c.1871A>T p.Q624L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV100459049; called by muse, mutect2, varscan2
- ENTPD7 | c.962G>C p.R321P | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100978500, COSV65112149; called by muse, mutect2, varscan2
- EPM2AIP1 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs1268947162, COSV99212781; called by muse, mutect2, varscan2
- FASTKD2 | c.1600A>T p.M534L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99379276; called by muse, mutect2, varscan2
- FAT3 | c.12432G>T p.Q4144H | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.834); catalogued as COSV99971385; called by muse, mutect2, varscan2
- FZD3 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99528404; called by muse, mutect2, varscan2
- GMPPA | c.1015A>T p.S339C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as COSV100354887; called by muse, mutect2, varscan2
- GPRC6A | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100114821; called by muse, mutect2, varscan2
- HK3 | c.1600+1G>A p.X534_splice | Splice Site (SNP) | VAF 29/71 reads (41%) | catalogued as COSV99459436; called by muse, mutect2, varscan2
- HSPG2 | c.10283G>A p.G3428D | Missense Mutation (SNP) | VAF 524/1396 reads (38%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.465); catalogued as rs1162141885, COSV101013559; called by muse, mutect2, varscan2
- HTT | c.1780C>T p.Q594* | Nonsense Mutation (SNP) | VAF 38/73 reads (52%) | catalogued as COSV100751276; called by muse, mutect2, varscan2
- IQGAP1 | c.452G>C p.C151S | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51583994, COSV99185380; called by muse, mutect2, varscan2
- IRF4 | c.1135C>A p.P379T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1159107414, COSV101110962; called by muse, mutect2, varscan2
- JMJD1C | c.2695-1G>T p.X899_splice | Splice Site (SNP) | VAF 48/97 reads (49%) | catalogued as COSV100550865; called by muse, mutect2, varscan2
- KIAA1210 | c.2230A>T p.S744C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV101274409; called by muse, mutect2, varscan2
- KLHL32 | c.498C>G p.F166L | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100987506, COSV65111488; called by muse, mutect2
- KNDC1 | c.2070-1G>A p.X690_splice | Splice Site (SNP) | VAF 96/172 reads (56%) | catalogued as COSV100466316; called by muse, mutect2, varscan2
- KNDC1 | c.2070G>T p.R690S | Missense Mutation (SNP) | VAF 94/171 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100466320; called by muse, mutect2, varscan2
- MAGEE2 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV100973219, COSV64897585; called by muse, mutect2, varscan2
- MCTP2 | c.2312T>C p.V771A | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100752540; called by muse, mutect2, varscan2
- MKKS | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs776936558, COSV100726325; called by muse, mutect2, varscan2
- MSANTD4 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV100108666, COSV57285057; called by muse, mutect2
- MYH6 | c.1899T>A p.S633R | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100677032; called by muse, mutect2, varscan2
- MYH7B | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99483327; called by muse, mutect2, varscan2
- NEXMIF | c.2173G>T p.E725* | Nonsense Mutation (SNP) | VAF 6/65 reads (9%) | catalogued as COSV50029392, COSV99279992, COSV99280430; called by muse, mutect2
- NIN | c.6243C>G p.N2081K (on ENST00000382041 / NM_182946.1; = p.N1368K on NM_016350.4) | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV55388737, COSV99815419; called by muse, mutect2
- NKX3-2 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 280/452 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as COSV101220010; called by muse, varscan2
- NPAP1 | c.3444G>T p.R1148S | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV100276237, COSV61511870; called by muse, mutect2, varscan2
- NRXN1 | c.3541C>A p.H1181N | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs377333818; called by muse, mutect2, varscan2
- NTSR2 | c.1143C>A p.H381Q | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.055); catalogued as COSV100184037; called by muse, mutect2, varscan2
- NUP210 | c.2059A>T p.T687S | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV99597088; called by muse, mutect2, varscan2
- OR2T11 | c.383G>C p.R128T | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV100424974; called by muse, mutect2, varscan2
- OR4K1 | c.403A>T p.I135F | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs760108085, COSV53459985, COSV99579454; called by muse, mutect2, varscan2
- OR52E8 | c.274T>A p.W92R | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101191099; called by muse, mutect2, varscan2
- PATL1 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100275269; called by muse, mutect2, varscan2
- PCDH12 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.594); catalogued as rs370147049; called by muse, mutect2, varscan2
- PCDHGA1 | c.1750C>A p.P584T | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as COSV100966112; called by muse, mutect2, varscan2
- PCLO | c.7421C>A p.P2474H | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as COSV100438189; called by muse, mutect2, varscan2
- PCLO | c.2545G>A p.V849I | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs547726879, COSV61660879; called by muse, mutect2, varscan2
- PM20D1 | c.877A>T p.T293S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.017); catalogued as COSV100900253; called by muse, mutect2, varscan2
- PPARGC1B | c.2497G>A p.D833N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.396); catalogued as COSV100495213; called by muse, mutect2, varscan2
- PPIP5K1 | c.778-2A>T p.X260_splice | Splice Site (SNP) | VAF 50/279 reads (18%) | catalogued as COSV100613550; called by muse, mutect2, varscan2
- PPL | c.2549A>T p.Y850F | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV99278681; called by muse, mutect2, varscan2
- PRAMEF7 | c.1045A>T p.T349S | Missense Mutation (SNP) | VAF 179/489 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100435174; called by muse, varscan2
- PTPN3 | c.803T>G p.F268C | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99355705, COSV99356265; called by muse, mutect2, varscan2
- PTPRB | c.970C>A p.L324M | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54231694, COSV99719075; called by muse, mutect2, varscan2
- PYHIN1 | c.643A>T p.I215L | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100932419; called by muse, mutect2, varscan2
- RABEP2 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 59/84 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765092338, COSV100707226; called by muse, mutect2, varscan2
- RP9 | c.556A>T p.K186* | Nonsense Mutation (SNP) | VAF 136/380 reads (36%) | catalogued as COSV99778052; called by muse, mutect2, varscan2
- RYR1 | c.5548G>T p.V1850L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.074); catalogued as COSV100616402, COSV100617089; called by muse, mutect2, varscan2
- SACS | c.8416A>G p.M2806V | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs941542740, COSV66546770; called by muse, mutect2, varscan2
- SALL4 | c.2286C>G p.D762E | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.415); catalogued as COSV99409878; called by muse, mutect2, varscan2
- SLC22A10 | c.1388T>C p.V463A | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV100236046; called by muse, mutect2, varscan2
- SLC41A2 | c.688C>G p.P230A | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.253); catalogued as COSV99316959; called by muse, mutect2
- SLC4A3 | c.1973-2A>T p.X658_splice | Splice Site (SNP) | VAF 19/58 reads (33%) | catalogued as COSV99813266; called by muse, mutect2, varscan2
- SLC5A1 | c.443T>A p.L148Q | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99833802; called by muse, mutect2, varscan2
- SMCHD1 | c.4441G>A p.V1481I | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99862641; called by muse, mutect2, varscan2
- ST6GAL2 | c.940A>T p.I314L | Missense Mutation (SNP) | VAF 42/168 reads (25%) | PolyPhen possibly damaging (0.558); catalogued as COSV100868304; called by muse, mutect2, varscan2
- TDP2 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV100016139; called by muse, mutect2, varscan2
- TINAG | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs867931815, COSV99450881; called by muse, mutect2, varscan2
- TLX2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as rs749625308, COSV99283786; called by muse, mutect2, varscan2
- TMEM45B | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV99859572; called by muse, mutect2, varscan2
- WFS1 | c.992T>A p.F331Y | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV99901629; called by muse, mutect2
- WIF1 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99682608, COSV99683449; called by muse, mutect2, varscan2
- ZC3H6 | c.1723T>C p.Y575H | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs1488045934, COSV100674837; called by muse, mutect2, varscan2
- ZCWPW2 | c.463T>A p.F155I | Missense Mutation (SNP) | VAF 154/408 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV101075345; called by muse, mutect2, varscan2
- ZFHX4 | c.7379G>T p.G2460V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.663); catalogued as COSV99268089; called by muse, mutect2
- ZNF423 | c.3601G>T p.E1201* (on ENST00000563137 / NM_001379286.1; = p.E1193* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 39/58 reads (67%) | catalogued as rs1555513517, COSV99283924; called by muse, mutect2, varscan2
- AHNAK | c.13107_13114del p.G4370Vfs*17 | Frame Shift Del (DEL) | VAF 14/152 reads (9%) | called by mutect2, pindel
- APOM | c.398dup p.M133Ifs*4 | Frame Shift Ins (INS) | VAF 18/58 reads (31%) | called by mutect2, varscan2
- FANCM | c.4369del p.R1457Dfs*4 | Frame Shift Del (DEL) | VAF 28/152 reads (18%) | called by mutect2, pindel, varscan2
- IGHM | c.20C>G p.T7S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.98); called by muse, mutect2, varscan2
- MRC1 | c.3483+1G>T p.X1161_splice | Splice Site (SNP) | VAF 52/271 reads (19%) | called by muse, mutect2, varscan2
- TUBB2A | c.1044C>A p.N348K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, varscan2
- ABCA13 | c.5865C>T p.I1955= | Silent (SNP) | VAF 31/216 reads (14%) | catalogued as rs746356057, COSV101330191; called by muse, mutect2, varscan2
- ADAM9 | c.1407A>T p.G469= | Silent (SNP) | VAF 94/175 reads (54%) | catalogued as COSV101166277; called by muse, mutect2, varscan2
- DOCK2 | c.2667C>T p.L889= | Silent (SNP) | VAF 70/192 reads (36%) | catalogued as COSV56952058; called by muse, mutect2, varscan2
- FAM172A | c.513A>T p.I171= | Silent (SNP) | VAF 90/237 reads (38%) | catalogued as COSV67938688; called by muse, mutect2, varscan2
- GJD3 | c.447C>T p.T149= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100492317; called by muse, mutect2, varscan2
- HEPHL1 | c.555G>A p.V185= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV100244439, COSV59897799; called by muse, mutect2
- HOXC6 | c.126G>T p.A42= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as COSV54536056, COSV99679207; called by muse, mutect2, varscan2
- IGKV3-11 | c.345T>A p.P115= | Silent (SNP) | VAF 53/248 reads (21%) | called by muse, mutect2, varscan2
- KPRP | c.1539A>T p.L513= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as COSV100908812; called by muse, mutect2, varscan2
- LIPF | c.618T>C p.Y206= | Silent (SNP) | VAF 60/113 reads (53%) | catalogued as rs1452034076, COSV99490643; called by muse, mutect2, varscan2
- MMP20 | c.294T>A p.P98= | Silent (SNP) | VAF 73/187 reads (39%) | catalogued as COSV99498007; called by muse, mutect2, varscan2
- OR1J2 | c.651A>T p.S217= | Silent (SNP) | VAF 64/93 reads (69%) | catalogued as COSV100093435; called by muse, mutect2, varscan2
- PCDHB13 | c.411A>G p.K137= | Silent (SNP) | VAF 178/551 reads (32%) | catalogued as COSV99507872; called by muse, mutect2, varscan2
- PPFIBP2 | c.387A>G p.T129= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV100207049; called by muse, mutect2, varscan2
- RFX2 | c.871C>A p.R291= | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as rs772420460, COSV100353996; called by muse, mutect2, varscan2
- RYR1 | c.8217T>A p.P2739= | Silent (SNP) | VAF 54/78 reads (69%) | catalogued as COSV100617090; called by muse, mutect2, varscan2
- RYR1 | c.10092G>A p.R3364= | Silent (SNP) | VAF 69/95 reads (73%) | catalogued as COSV100617092; called by muse, mutect2, varscan2
- SLITRK2 | c.579A>G p.L193= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV100158248; called by muse, mutect2, varscan2
- UGP2 | c.783G>A p.L261= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV100451769; called by muse, mutect2, varscan2
- ZZZ3 | c.2259A>T p.P753= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV100890458; called by muse, mutect2, varscan2
- C3orf52 | c.468-111T>A | Intron (SNP) | VAF 31/85 reads (36%) | catalogued as COSV99332683; called by muse, mutect2, varscan2
- RERE | c.830+15447C>T | Intron (SNP) | VAF 42/103 reads (41%) | catalogued as COSV100557382; called by muse, mutect2, varscan2
- RERE | c.830+15446G>A | Intron (SNP) | VAF 42/104 reads (40%) | catalogued as COSV100557383; called by muse, mutect2, varscan2
